Somatic mutation profile of tumor specimen 0DIAC0 from CCDI case PBBVJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 22.2 years (8,120 days).
Specimen 0DIAC0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22b76074-62a5-4a8e-a669-d0d81579b92f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIACF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92a1ed77-2a30-4be5-a857-251e85c7bc22

The open-access MAF lists 8 somatic variants for this specimen: 2 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 280/964 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- CACNA1B | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- ABCC11 | c.1278C>T p.L426= | Silent (SNP) | VAF 46/1456 reads (3%) | called by muse, mutect2
- CPVL | c.1170C>T p.I390= | Silent (SNP) | VAF 66/1172 reads (6%) | catalogued as rs759525082, COSV55300312; called by muse, mutect2
- FHL5 | c.63A>G p.V21= | Silent (SNP) | VAF 255/866 reads (29%) | catalogued as rs1283668437; called by muse, mutect2, varscan2
- LRRK1 | c.2805T>C p.F935= | Silent (SNP) | VAF 46/902 reads (5%) | called by muse, mutect2
- PRAF2 | c.141C>T p.N47= | Silent (SNP) | VAF 46/574 reads (8%) | called by muse, mutect2
- ADCY4 | c.3081+42G>C | Intron (SNP) | VAF 10/294 reads (3%) | called by muse, mutect2
